Somatic mutation profile of tumor specimen TARGET-30-PAKZRE-01A (aliquot TARGET-30-PAKZRE-01A-01W) from TARGET case TARGET-30-PAKZRE, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 3.0 years (1,083 days).
Specimen TARGET-30-PAKZRE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e28acf86-ad9a-4b7e-aced-c0b0328c4ab6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKZRE-10A (Blood Derived Normal), aliquot TARGET-30-PAKZRE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70b993b-dc3d-40b3-a8a7-b6b74569b1a0

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 3, Silent 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.5542G>T p.E1848* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV61370494; called by mutect2, varscan2
- BTBD7 | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 107/240 reads (45%) | catalogued as COSV58291032; called by mutect2, varscan2
- CBLL2 | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 140/309 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.181); catalogued as COSV60370461; called by muse, mutect2, varscan2
- EPHB2 | c.1927C>A p.P643T (on ENST00000400191 / NM_001309193.2; = p.P644T on NM_004442.7) | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV104424382, COSV65867188; called by muse, mutect2, varscan2
- GPM6A | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs768834518, COSV54539879; called by muse, mutect2, varscan2
- IRX3 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1490846942; called by mutect2, varscan2
- NR3C2 | c.2524C>T p.Q842* | Nonsense Mutation (SNP) | VAF 107/229 reads (47%) | catalogued as rs1553987070, COSV61000667; called by muse, mutect2, varscan2
- PEX5 | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV56958817; called by muse, mutect2, varscan2
- RELT | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs758853136, COSV50361161; called by mutect2, varscan2
- TCHH | c.3422G>T p.R1141L | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.013); catalogued as COSV64278123; called by muse, mutect2, varscan2
- TGM4 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV56096943; called by muse, mutect2, varscan2
- ZNF275 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781858126, COSV64705196; called by muse, mutect2, varscan2
- CD3D | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERV3-1 | c.511T>G p.W171G | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- GSDMB | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 58/1018 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- NOTCH4 | c.2150G>T p.C717F | Missense Mutation (SNP) | VAF 259/579 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACTBL2 | c.87G>T p.R29= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV70661884; called by muse, mutect2, varscan2
- IPO7 | c.2403A>G p.L801= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV65687255; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847949 T>C | 5'Flank (SNP) | VAF 86/189 reads (46%) | catalogued as rs368388768; called by muse, mutect2, varscan2
- PSG5 | c.431-2996G>T | Intron (SNP) | VAF 272/570 reads (48%) | catalogued as COSV61653857; called by muse, mutect2, varscan2
